Somatic mutation profile of tumor specimen TARGET-10-PARAJY-09A (aliquot TARGET-10-PARAJY-09A-01D) from TARGET case TARGET-10-PARAJY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (862 days).
Specimen TARGET-10-PARAJY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 050be7e3-f089-4a38-80e4-099151c12ac6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAJY-10A (Blood Derived Normal), aliquot TARGET-10-PARAJY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d4dde67-c785-4311-8c9d-d275261267c9

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as CD083323, CM1414600, CM971449; called by muse, mutect2, varscan2
- PXDNL | c.4109C>T p.A1370V | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs769579619, COSV100684910, COSV62477078, COSV62496975; called by muse, mutect2, varscan2
- HUNK | c.1173+1dup | Frame Shift Ins (INS) | VAF 29/123 reads (24%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SMG6 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANK3 | c.4632G>A p.S1544= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs146324308; called by muse, mutect2
- CCDC110 | c.900C>T p.D300= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs770507320, COSV56871446; called by muse, mutect2, varscan2
- OTOG | c.1887C>T p.Y629= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs759196357; called by muse, mutect2, varscan2
- RARRES2P7 | n.52C>T | RNA (SNP) | VAF 12/38 reads (32%) | catalogued as rs1297975148; called by muse, mutect2, varscan2
